Somatic mutation profile of tumor specimen TCGA-IN-7806-01A (aliquot TCGA-IN-7806-01A-11D-2053-08) from TCGA case TCGA-IN-7806, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 50.4 years (18,404 days).
Specimen TCGA-IN-7806-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9760ec91-98ad-495c-803a-fd9ec3014f23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-7806-10A (Blood Derived Normal), aliquot TCGA-IN-7806-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd2c4a1a-1dc4-48d1-b7ab-6f8960102245

The open-access MAF lists 76 somatic variants for this specimen: 62 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 48, Silent 14, Nonsense Mutation 6, Splice Site 3, Frame Shift Del 2, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEN1 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894264, CM040456, CM981277, COSV53641849, COSV53646830; ClinVar: pathogenic; called by muse, mutect2
- MEN1 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as rs1057520733, CM981266, COSV53642420; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 12/27 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAD10 | c.2989A>C p.K997Q | Missense Mutation (SNP) | VAF 117/301 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58161150; called by muse, mutect2, varscan2
- ACVR1B | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460557299, COSV57776372, COSV57780549; called by muse, mutect2, varscan2
- AL031777.2 | c.74A>C p.Q25P | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs1225978609, COSV61912241; called by muse, mutect2, varscan2
- AP2A1 | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV62820203; called by muse, mutect2, varscan2
- APBA2 | c.2113G>A p.G705R | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs753314225, COSV68794139; called by muse, mutect2, varscan2
- ATP2B3 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.055); catalogued as rs782560581, COSV54857341; called by muse, mutect2, varscan2
- C10orf71 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.28); catalogued as COSV60510995; called by muse, mutect2, varscan2
- C2orf42 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV52452111; called by muse, mutect2, varscan2
- CARNS1 | c.2405G>A p.R802H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs776062703, COSV57047398; called by muse, mutect2, varscan2
- CNTN5 | c.745del p.Q249Rfs*23 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as COSV54280074; called by mutect2, pindel, varscan2
- COL5A2 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV66407372; called by muse, mutect2, varscan2
- COL5A3 | c.4720G>T p.V1574F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53416777; called by muse, mutect2, varscan2
- CYLD | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); catalogued as COSV61096665; called by muse, mutect2, varscan2
- DPYS | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV60912098; called by muse, mutect2, varscan2
- DTX4 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs749024578, COSV57093692; called by muse, mutect2, varscan2
- FASN | c.2692A>G p.T898A | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV60757641; called by muse, mutect2, varscan2
- FNDC11 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs769043567, COSV64443301; called by muse, mutect2, varscan2
- GLB1L | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 97/277 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55475270; called by muse, mutect2, varscan2
- GRID1 | c.2323C>A p.Q775K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV60045441; called by muse, mutect2, varscan2
- IARS1 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1184030038, COSV65113373; called by muse, mutect2, varscan2
- IKBKE | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs377576134, COSV100898114; called by muse, mutect2, varscan2
- IL31 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs755248798, COSV65476579; called by muse, mutect2, varscan2
- JAKMIP1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV51541382; called by muse, mutect2, varscan2
- LAMA1 | c.9152T>C p.V3051A | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV67542049; called by muse, mutect2, varscan2
- LIMCH1 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58292236; called by muse, mutect2, varscan2
- LRBA | c.6728A>G p.Y2243C | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63961312; called by muse, mutect2, varscan2
- LRP2 | c.3667+1G>A p.X1223_splice | Splice Site (SNP) | VAF 115/385 reads (30%) | catalogued as rs752197557, COSV55546404; called by muse, mutect2
- MCF2 | c.30G>T p.K10N | Missense Mutation (SNP) | VAF 137/195 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58491930; called by muse, mutect2, varscan2
- MSH6 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1057520605, COSV52285152; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC17 | c.10066G>A p.E3356K | Missense Mutation (SNP) | VAF 18/643 reads (3%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.952); catalogued as COSV60294986; called by muse, mutect2
- MYO1B | c.331G>T p.G111* | Nonsense Mutation (SNP) | VAF 43/178 reads (24%) | catalogued as COSV58436056; called by muse, mutect2, varscan2
- MYO7A | c.3139C>T p.R1047C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782095541, COSV68684842; called by muse, mutect2, varscan2
- NETO1 | c.1498A>G p.T500A | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.956); catalogued as COSV55012626; called by muse, mutect2, varscan2
- PDHA2 | c.477T>A p.Y159* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as COSV54777026, COSV54781078; called by muse, mutect2, varscan2
- PHPT1 | c.162G>A p.A54= | Splice Region (SNP) | VAF 33/139 reads (24%) | catalogued as COSV56034483; called by muse, mutect2, varscan2
- PKD2 | c.2536G>A p.V846M | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52940383; called by muse, mutect2, varscan2
- PRAMEF17 | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 15/421 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as COSV65816576; called by muse, mutect2
- PRKCQ | c.1965+1G>T p.X655_splice | Splice Site (SNP) | VAF 7/143 reads (5%) | catalogued as COSV54116340; called by muse, mutect2
- PXDN | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs746584021, COSV53234690; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3064G>A p.V1022I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.1); catalogued as rs897601785, COSV54762811; called by muse, mutect2, varscan2
- RELN | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 23/94 reads (24%) | catalogued as COSV59019305, COSV59025265; called by muse, mutect2, varscan2
- RSPH9 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV100937762, COSV64665586; called by muse, mutect2, varscan2
- RYR2 | c.3256C>T p.R1086* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as rs371303783, COSV63704672; called by muse, mutect2, varscan2
- SEC31B | c.981G>T p.W327C | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV64825068; called by muse, mutect2, varscan2
- SLC35F5 | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV55519870; called by muse, mutect2, varscan2
- SLITRK2 | c.2474A>C p.K825T | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59427795; called by muse, mutect2, varscan2
- STYXL1 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs147059565; called by muse, mutect2
- TAS2R43 | c.675A>G p.I225M | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1233544640, COSV67861096; called by muse, varscan2
- TEKT5 | c.1237T>A p.L413M | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as COSV51589131, COSV51590982; called by muse, mutect2, varscan2
- TEX14 | c.2721-1G>C p.X907_splice (on ENST00000240361 / NM_001201457.2; = p.X901_splice on NM_031272.5) | Splice Site (SNP) | VAF 12/46 reads (26%) | catalogued as COSV53623710; called by muse, mutect2, varscan2
- TMEM184C | c.398T>A p.L133Q | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56854395; called by muse, mutect2
- TRIM6-TRIM34 | c.1705A>G p.K569E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.122); catalogued as rs991942139, COSV61457840; called by muse, mutect2, varscan2
- TTN | c.31541T>C p.I10514T (on ENST00000591111; = p.I9587T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | PolyPhen benign (0); catalogued as COSV60250917; called by muse, mutect2
- UCP3 | c.179G>C p.G60A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58368763, COSV58369032; called by muse, mutect2, varscan2
- UNC13C | c.4713G>A p.P1571= | Splice Region (SNP) | VAF 23/85 reads (27%) | catalogued as rs1445102357, COSV52841330; called by muse, mutect2, varscan2
- VPS52 | c.1508A>G p.D503G | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV71403589; called by muse, mutect2, varscan2
- WDR76 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753285676, COSV51040433; called by muse, mutect2, varscan2
- EFR3A | c.2181_2188del p.F728Ifs*6 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel, varscan2
- HDC | c.1896dup p.L633Tfs*12 | Frame Shift Ins (INS) | VAF 33/118 reads (28%) | called by mutect2, pindel, varscan2
- ACTL7A | c.1035G>A p.K345= | Silent (SNP) | VAF 54/150 reads (36%) | catalogued as COSV61777143; called by muse, mutect2, varscan2
- AHI1 | c.756G>A p.L252= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as COSV55631955; called by muse, mutect2, varscan2
- ANK2 | c.3783A>G p.L1261= | Silent (SNP) | VAF 44/78 reads (56%) | catalogued as COSV52179623; called by muse, mutect2, varscan2
- C5AR1 | c.90T>C p.S30= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as COSV61893093; called by muse, mutect2, varscan2
- DCAF4L2 | c.969C>T p.N323= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as rs370189631, COSV60481200; called by muse, mutect2, varscan2
- DNAJC3 | c.201C>T p.D67= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV65132547; called by muse, varscan2
- DNPH1 | c.66C>T p.A22= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV52732693; called by muse, mutect2, varscan2
- DYNC2H1 | c.8739A>G p.E2913= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV62102753; called by muse, mutect2
- ILVBL | c.457C>T p.L153= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV54621689, COSV99654870; called by muse, mutect2, varscan2
- NYAP2 | c.705G>A p.A235= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as rs942651280, COSV56013341; called by muse, mutect2, varscan2
- RYR2 | c.6447T>A p.I2149= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV63704678; called by muse, mutect2, varscan2
- SMG5 | c.2667C>T p.I889= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs1466829581, COSV52744666; called by muse, mutect2, varscan2
- TBX15 | c.1647C>T p.N549= (on ENST00000369429 / NM_001330677.2; = p.N443= on NM_152380.3) | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV52874650, COSV99253681; called by muse, mutect2, varscan2
- ZMYM2 | c.3277C>T p.L1093= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV67036632; called by muse, mutect2, varscan2
